Somatic mutation profile of tumor specimen MP2PRT-PATGDB-TMP1-A (aliquot MP2PRT-PATGDB-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATGDB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,335 days).
Specimen MP2PRT-PATGDB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfe2f35e-5765-4350-aff3-cebd9dd5354c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGDB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGDB-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee2d1ab-0c04-459d-b088-497887a50b86

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 3, 5'Flank 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.13298C>T p.A4433V (on ENST00000409039; = p.A4372V on NM_207437.3) | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs374117121; called by muse, varscan2
- KCND2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 86/285 reads (30%) | catalogued as rs748699001, COSV58567795; called by muse, mutect2, varscan2
- OR5AC2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | catalogued as rs200017985; called by muse, mutect2, varscan2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 17/254 reads (7%) | catalogued as COSV56264314; called by muse, mutect2
- SLC22A2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768194904, COSV65266300; called by muse, mutect2
- SPAG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs769344647, COSV52558730, COSV52559172; called by muse, mutect2, varscan2
- TIGIT | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 134/433 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777679603, COSV67329374; called by muse, mutect2, varscan2
- GFRA3 | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 114/470 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBL1X | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- MISP | c.1125G>A p.A375= | Silent (SNP) | VAF 89/549 reads (16%) | catalogued as rs750376997; called by muse, mutect2, varscan2
- NEBL | c.174G>A p.P58= | Silent (SNP) | VAF 37/270 reads (14%) | catalogued as rs758912425; called by muse, mutect2, varscan2
- PABPC4L | c.516C>T p.F172= | Silent (SNP) | VAF 16/400 reads (4%) | called by muse, mutect2
- PEX14 | c.483G>A p.Q161= | Silent (SNP) | VAF 23/234 reads (10%) | called by muse, mutect2, varscan2
- VPS37D | c.732G>A p.S244= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915706 C>G | 5'Flank (SNP) | VAF 32/582 reads (5%) | called by muse, mutect2
- ARHGEF4 | c.-487C>T | 5'UTR (SNP) | VAF 15/296 reads (5%) | catalogued as rs1303179100; called by muse, mutect2
- ARHGEF4 | c.-109+16C>T | Intron (SNP) | VAF 26/457 reads (6%) | called by muse, mutect2
